Somatic mutation profile of tumor specimen TCGA-CV-A45W-01A (aliquot TCGA-CV-A45W-01A-11D-A25D-08) from TCGA case TCGA-CV-A45W, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 76.0 years (27,743 days).
Specimen TCGA-CV-A45W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b582b8a-a517-4646-bb84-a431b4b2709e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-A45W-10A (Blood Derived Normal), aliquot TCGA-CV-A45W-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/93b9c94c-fd4c-4eb5-a46b-7830f30d756e

The open-access MAF lists 654 somatic variants for this specimen: 500 protein-altering or splice-affecting, 132 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 411, Silent 132, Nonsense Mutation 49, Frame Shift Del 14, Splice Site 11, RNA 10, Intron 7, Frame Shift Ins 7, Splice Region 6, 3'Flank 2, 3'UTR 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DCC | c.4124C>A p.P1375H | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.478); catalogued as rs387906555, COSV101473444; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1268G>C p.G423A (on ENST00000281708 / NM_001349798.2; = p.G343A on NM_018315.5) | Missense Mutation (SNP) | VAF 13/160 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55892390, COSV99657129; called by muse, mutect2
- H3C2 | c.82A>G p.K28E | Missense Mutation (SNP) | VAF 32/216 reads (15%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.046); catalogued as COSV99451661; called by muse, mutect2, varscan2
- TP53 | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 14/66 reads (21%) | hotspot (GDC flag); catalogued as rs201744589, CM031387, COSV52661551, COSV52761493, COSV53353479, COSV53790595; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 7/36 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCF1 | c.229C>T p.R77* | Nonsense Mutation (SNP) | VAF 17/101 reads (17%) | catalogued as rs1561786344, COSV58228142; called by muse, mutect2, varscan2
- ABTB1 | c.1299G>T p.E433D (on ENST00000232744 / NM_172027.3; = p.E291D on NM_032548.3) | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV99230057; called by muse, mutect2, varscan2
- AC018630.4 | c.271G>T p.G91C | Missense Mutation (SNP) | VAF 14/281 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV99958568; called by muse, mutect2
- AC104452.1 | c.1289G>T p.C430F | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99648690; called by muse, mutect2, varscan2
- ACAP3 | c.1061G>T p.W354L | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100686666; called by muse, mutect2, varscan2
- ACTRT2 | c.401C>A p.P134H | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101007649; called by muse, mutect2
- ADAM7 | c.1927G>T p.D643Y | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.556); catalogued as COSV51547818, COSV99444750; called by muse, mutect2
- ADAMTS12 | c.1114C>A p.P372T | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100711537; called by muse, mutect2, varscan2
- ADAMTS3 | c.1016A>T p.Q339L | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs1249311938, COSV99711833; called by muse, mutect2, varscan2
- ADAMTS6 | c.431C>A p.T144N | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as COSV101125305; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4024G>T p.G1342C | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.401); catalogued as COSV99720605; called by muse, mutect2
- ADD2 | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.688); catalogued as COSV100036313; called by muse, mutect2, varscan2
- ADGRB3 | c.1834T>C p.Y612H | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101001606; called by muse, mutect2, varscan2
- ADGRB3 | c.2720G>C p.R907P | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV53252143; called by muse, mutect2, varscan2
- ADGRE1 | c.722G>T p.S241I | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV99164976; called by muse, mutect2
- ADNP | c.2927C>T p.P976L | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.018); catalogued as rs1463522238, COSV100823831; called by muse, mutect2
- AFDN | c.3862G>T p.E1288* | Nonsense Mutation (SNP) | VAF 8/80 reads (10%) | catalogued as COSV100653375; called by muse, mutect2
- AKAP10 | c.1237G>A p.D413N | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.572); catalogued as COSV99855552; called by muse, mutect2, varscan2
- AKAP3 | c.896C>G p.S299C | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99962527; called by muse, mutect2
- AL592490.1 | c.737C>A p.T246N | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.773); catalogued as COSV101308262; called by muse, mutect2, varscan2
- ALG13 | c.3118G>A p.D1040N | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99322841; called by muse, mutect2, varscan2
- ANO5 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.887); catalogued as rs770413331, COSV100202107, COSV99048661; ClinVar: uncertain significance; called by muse, mutect2
- AOPEP | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99469227; called by muse, mutect2, varscan2
- APBB1IP | c.313A>G p.S105G | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV63303216; called by muse, mutect2
- APC2 | c.1431C>A p.D477E | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV99279752; called by muse, mutect2, varscan2
- AQP8 | c.90G>A p.W30* | Nonsense Mutation (SNP) | VAF 28/336 reads (8%) | catalogued as rs1403618437, COSV54846695, COSV99564107; called by muse, mutect2
- AQR | c.3755G>T p.G1252V | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99334454; called by muse, mutect2
- ARHGEF10L | c.3665G>C p.R1222P | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV99393599; called by muse, mutect2, varscan2
- ARHGEF11 | c.893A>G p.Y298C | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.048); catalogued as rs766925017, COSV100810393; called by muse, mutect2, varscan2
- ASB2 | c.111G>T p.L37F | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.36); catalogued as COSV100279532; called by muse, mutect2
- ATP6V0A4 | c.1229G>T p.G410V | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100023523; called by muse, mutect2, varscan2
- ATP9B | c.2839-1G>A p.X947_splice | Splice Site (SNP) | VAF 10/106 reads (9%) | catalogued as rs1168143429, COSV100304026; called by muse, mutect2, varscan2
- B3GALNT1 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.242); catalogued as COSV100252136; called by muse, mutect2, varscan2
- BARD1 | c.1450A>G p.K484E | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.18); catalogued as COSV99639589; called by muse, mutect2, varscan2
- BHMT2 | c.73G>T p.G25* | Nonsense Mutation (SNP) | VAF 8/132 reads (6%) | catalogued as COSV104369908, COSV99670260; called by muse, mutect2
- BOC | c.1696C>T p.R566* | Nonsense Mutation (SNP) | VAF 5/91 reads (5%) | catalogued as rs1038611376, COSV99848041, COSV99848956; called by muse, mutect2
- BRPF1 | c.1316G>A p.R439H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771693624, COSV100121388; called by muse, mutect2, varscan2
- C1orf162 | c.430G>T p.D144Y | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100636235; called by muse, mutect2, varscan2
- C2CD3 | c.940A>G p.K314E | Missense Mutation (SNP) | VAF 11/203 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100487223, COSV58095333; called by muse, mutect2
- C4orf45 | c.224G>T p.S75I | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1405146908, COSV101465161; called by muse, mutect2
- C6 | c.1537G>T p.E513* | Nonsense Mutation (SNP) | VAF 27/127 reads (21%) | catalogued as COSV99667607; called by muse, mutect2, varscan2
- C7orf50 | c.178C>A p.P60T | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.915); catalogued as COSV100657684; called by muse, mutect2
- CA8 | c.355T>A p.W119R | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100527225; called by muse, mutect2, varscan2
- CACNA1A | c.2050G>A p.V684M | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100802949, COSV64213082; called by muse, mutect2, varscan2
- CAGE1 | c.2062G>T p.G688* (on ENST00000512086; = p.G552* on NM_205864.3) | Nonsense Mutation (SNP) | VAF 3/31 reads (10%) | catalogued as COSV99700039; called by muse, mutect2
- CALCRL | c.175C>T p.Q59* | Nonsense Mutation (SNP) | VAF 10/115 reads (9%) | catalogued as COSV101131028; called by muse, mutect2
- CALM2 | c.68A>G p.D23G | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV99700971; called by muse, mutect2, varscan2
- CANX | c.879C>G p.I293M | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99910616; called by muse, mutect2, varscan2
- CAPN13 | c.547C>G p.L183V | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV54429900, COSV99700864; called by muse, mutect2
- CASQ1 | c.302A>T p.D101V | Missense Mutation (SNP) | VAF 15/208 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as COSV100927349; called by muse, mutect2
- CASS4 | c.403G>T p.D135Y | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.869); catalogued as COSV64385655; called by muse, mutect2, varscan2
- CAVIN2 | c.680G>C p.R227T | Missense Mutation (SNP) | VAF 16/175 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.521); catalogued as COSV100414315; called by muse, mutect2
- CBLB | c.1057A>G p.I353V | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.563); catalogued as COSV99914082; called by muse, mutect2
- CCDC171 | c.2932G>T p.G978* | Nonsense Mutation (SNP) | VAF 12/49 reads (24%) | catalogued as COSV99899795; called by muse, mutect2, varscan2
- CCDC181 | c.305A>T p.N102I | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV100890368; called by muse, mutect2, varscan2
- CCNF | c.208G>C p.A70P | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.022); catalogued as COSV99564027; called by muse, mutect2
- CD163 | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.714); catalogued as COSV100776065; called by muse, mutect2, varscan2
- CD1A | c.66G>C p.K22N | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs3087217, COSV99192564; called by muse, mutect2, varscan2
- CD1A | c.444G>A p.W148* | Nonsense Mutation (SNP) | VAF 16/109 reads (15%) | catalogued as rs779725639, COSV99192567; called by muse, mutect2, varscan2
- CD1B | c.221G>C p.G74A | Missense Mutation (SNP) | VAF 51/396 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); catalogued as COSV100939281; called by muse, mutect2, varscan2
- CD200R1 | c.961G>A p.D321N (on ENST00000471858 / NM_170780.3; = p.D344N on NM_138806.4) | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs1262971972, COSV99866621, COSV99867677; called by muse, mutect2
- CD244 | c.649G>A p.D217N (on ENST00000368033 / NM_001166663.2; = p.D212N on NM_016382.4) | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.096); catalogued as COSV100458773; called by muse, mutect2, varscan2
- CD38 | c.95T>C p.V32A | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.051); catalogued as COSV99882964; called by muse, mutect2, varscan2
- CDC42 | c.566T>G p.V189G | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as COSV100212664; called by muse, mutect2, varscan2
- CDH12 | c.1090C>A p.P364T | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.533); catalogued as COSV101203187; called by muse, mutect2, varscan2
- CEACAM18 | c.26G>T p.S9I | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as COSV101140621; called by mutect2, varscan2
- CEACAM5 | c.1654G>A p.G552S | Missense Mutation (SNP) | VAF 15/177 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.768); catalogued as COSV99704106; called by muse, mutect2
- CEP112 | c.1028T>C p.I343T | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.109); catalogued as COSV101211062; called by muse, mutect2, varscan2
- CFAP221 | c.876C>A p.H292Q | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV99733004; called by muse, mutect2, varscan2
- CFAP65 | c.360C>T p.P120= (on ENST00000341552 / NM_194302.4; = p.P55= on NM_152389.4) | Splice Region (SNP) | VAF 14/73 reads (19%) | catalogued as rs368785817; called by muse, mutect2, varscan2
- CFTR | c.3640G>A p.D1214N | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1221344688, COSV99138620; called by muse, mutect2, varscan2
- CGAS | c.1034C>T p.S345L | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as COSV100943690; called by muse, mutect2
- CHL1 | c.1976G>T p.W659L (on ENST00000397491 / NM_001253387.1; = p.W675L on NM_006614.4) | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99852031; called by muse, mutect2
- CLCN1 | c.128A>T p.Q43L | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.074); catalogued as CM1212568, COSV100578404; called by muse, mutect2, varscan2
- CLTC | c.2959G>T p.E987* | Nonsense Mutation (SNP) | VAF 13/199 reads (7%) | catalogued as COSV52253308, COSV99292763; called by muse, mutect2
- CLYBL | c.958G>A p.D320N | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs989315798, COSV100185585; called by muse, mutect2, varscan2
- CMPK1 | c.363C>A p.F121L | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV64101651; called by mutect2, varscan2
- CNTNAP2 | c.3395C>A p.P1132H | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.559); catalogued as COSV100670050, COSV62267647; called by muse, mutect2, varscan2
- CNTNAP4 | c.1299C>A p.Y433* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as COSV100272770; called by muse, mutect2, varscan2
- CNTNAP5 | c.2306G>A p.R769K | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as rs62171340, COSV101443951; called by muse, mutect2, varscan2
- COL14A1 | c.1467G>C p.E489D | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV99920283; called by muse, mutect2
- COL22A1 | c.3243T>A p.G1081= | Splice Region (SNP) | VAF 6/60 reads (10%) | catalogued as COSV100280122, COSV57364670; called by muse, mutect2, varscan2
- COL26A1 | c.263C>A p.P88H | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100561658, COSV100561961; called by muse, mutect2, varscan2
- COL9A2 | c.1549G>A p.G517S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101028710; called by muse, mutect2
- COQ10A | c.596C>G p.S199C | Missense Mutation (SNP) | VAF 17/204 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100370016; called by muse, mutect2
- COQ3 | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.94); catalogued as COSV99632931; called by muse, mutect2, varscan2
- CPED1 | c.301C>T p.L101F | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100121336; called by muse, mutect2, varscan2
- CSMD3 | c.10249C>G p.P3417A (on ENST00000297405 / NM_001363185.1; = p.P3248A on NM_052900.3) | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99843997; called by muse, mutect2, varscan2
- CSMD3 | c.9200G>A p.R3067K (on ENST00000297405 / NM_001363185.1; = p.R2898K on NM_052900.3) | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.1); catalogued as COSV99843999; called by muse, mutect2
- CSMD3 | c.7958G>T p.R2653L (on ENST00000297405 / NM_001363185.1; = p.R2549L on NM_052900.3) | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV99844002, COSV99844666; called by muse, mutect2, varscan2
- CSMD3 | c.4809C>G p.N1603K (on ENST00000297405 / NM_001363185.1; = p.N1499K on NM_052900.3) | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV52187080, COSV99844010; called by muse, mutect2, varscan2
- CSMD3 | c.1286C>A p.P429Q | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.991); catalogued as rs535411359, COSV99823742, COSV99828848; called by muse, mutect2
- CWC27 | c.289G>T p.G97* | Nonsense Mutation (SNP) | VAF 9/172 reads (5%) | catalogued as COSV101126568; called by muse, mutect2
- CWF19L2 | c.1664G>T p.G555V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99979674; called by muse, mutect2, varscan2
- CYP2C19 | c.715T>C p.F239L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV100990611; called by muse, mutect2, varscan2
- DBI | c.127G>A p.E43K (on ENST00000355857 / NM_001079862.3; = p.E60K on NM_020548.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as rs1417956542, COSV100276014; called by muse, mutect2
- DCAF12L1 | c.1184C>T p.S395L | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs768239477, COSV100948355; called by muse, mutect2, varscan2
- DCC | c.4123C>A p.P1375T | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV71431455, COSV71441327; called by muse, mutect2, varscan2
- DEPDC1 | c.2185G>T p.E729* (on ENST00000456315 / NM_001114120.3; = p.E445* on NM_017779.6) | Nonsense Mutation (SNP) | VAF 26/184 reads (14%) | catalogued as COSV100920450; called by muse, mutect2, varscan2
- DGKA | c.594G>T p.M198I | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV100093320; called by muse, mutect2, varscan2
- DGKA | c.1052G>T p.S351I | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV59387305; called by muse, mutect2
- DGKD | c.1417G>T p.E473* (on ENST00000264057 / NM_152879.3; = p.E429* on NM_003648.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 8/68 reads (12%) | catalogued as COSV99897238; called by muse, mutect2, varscan2
- DHX32 | c.2080C>T p.P694S | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99501882; called by muse, mutect2, varscan2
- DNAH14 | c.772A>G p.R258G (on ENST00000445597; = p.R131G on NM_144989.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.037); catalogued as COSV100835961; called by muse, mutect2, varscan2
- DNAH2 | c.8559G>T p.E2853D | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.147); catalogued as COSV101209540; called by muse, mutect2
- DNAH2 | c.8559+1G>T p.X2853_splice | Splice Site (SNP) | VAF 8/89 reads (9%) | catalogued as COSV101209541; called by muse, mutect2
- DNAH5 | c.460G>C p.D154H | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99452005; called by muse, mutect2, varscan2
- DNAJC25 | c.709C>T p.Q237* | Nonsense Mutation (SNP) | VAF 3/44 reads (7%) | catalogued as rs868430633; called by muse, mutect2
- DPPA4 | c.358C>A p.R120S | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100169616, COSV59509170; called by muse, mutect2
- DPT | c.162G>T p.Q54H | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV100892159; called by muse, mutect2, varscan2
- DPYD | c.861A>T p.E287D | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100929281; called by muse, mutect2, varscan2
- DSC1 | c.892C>G p.P298A | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV99938112; called by muse, mutect2
- DSCAM | c.2085G>T p.Q695H | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV101261255; called by muse, mutect2, varscan2
- DSEL | c.1013G>T p.G338V | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100025985; called by muse, mutect2, varscan2
- EEA1 | c.3822A>T p.L1274F | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.573); catalogued as COSV100468318; called by muse, mutect2, varscan2
- EIF4G1 | c.2239C>T p.R747* (on ENST00000346169 / NM_198241.3; = p.R552* on NM_004953.5) | Nonsense Mutation (SNP) | VAF 8/152 reads (5%) | catalogued as COSV100072200; called by muse, mutect2
- ELAPOR2 | c.2062G>A p.D688N (on ENST00000450689 / NM_001142749.3; = p.D521N on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.071); catalogued as COSV99789251; called by muse, mutect2, varscan2
- EMSY | c.3742G>A p.A1248T | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV100595967; called by muse, mutect2, varscan2
- ENPP1 | c.2227C>A p.P743T | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1204150921, COSV100719625; called by muse, mutect2, varscan2
- EPAS1 | c.1014G>T p.M338I | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99763516; called by muse, mutect2, varscan2
- EPB41L1 | c.2572G>T p.V858L | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99151412; called by muse, mutect2
- EPHA2 | c.274G>T p.E92* | Nonsense Mutation (SNP) | VAF 14/83 reads (17%) | catalogued as COSV100626256; called by muse, mutect2, varscan2
- EPHB1 | c.1742A>G p.H581R | Missense Mutation (SNP) | VAF 14/257 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV101214033; called by muse, mutect2
- EPPK1 | c.5162C>T p.P1721L | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as COSV101599933; called by muse, mutect2, varscan2
- ERP44 | c.380G>C p.R127P | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52432717, COSV99316608; called by muse, mutect2, varscan2
- ERV3-1 | c.411C>G p.F137L | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as COSV99275999; called by mutect2, varscan2
- FAM135B | c.2090G>T p.W697L | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as COSV99426522; called by muse, mutect2, varscan2
- FAM135B | c.256G>T p.A86S | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.01); catalogued as COSV99357910; called by muse, mutect2, varscan2
- FAM184A | c.1021C>A p.Q341K | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.977); catalogued as COSV100138204, COSV58854362; called by muse, mutect2, varscan2
- FAM20B | c.720G>C p.R240S | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99762560; called by muse, mutect2, varscan2
- FAM220A | c.692T>A p.L231H | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV100510850; called by muse, mutect2, varscan2
- FAT3 | c.5495C>A p.A1832E | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV99969473; called by muse, mutect2
- FAT3 | c.5497A>T p.I1833F | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99969477; called by muse, mutect2
- FAT3 | c.7726G>A p.D2576N | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99969480; called by muse, mutect2, varscan2
- FCN2 | c.486C>G p.Y162* | Nonsense Mutation (SNP) | VAF 8/62 reads (13%) | catalogued as rs1399315160, COSV99391413; called by muse, mutect2, varscan2
- FCRL3 | c.998G>T p.R333I | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.06); catalogued as COSV100943475; called by muse, mutect2, varscan2
- FGF14 | c.61A>G p.K21E | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as COSV101087289; called by muse, mutect2, varscan2
- FNBP4 | c.312A>G p.T104= | Splice Region (SNP) | VAF 28/244 reads (11%) | catalogued as COSV99771908; called by muse, mutect2, varscan2
- FNIP1 | c.2917G>T p.E973* | Nonsense Mutation (SNP) | VAF 11/116 reads (9%) | catalogued as COSV100330556; called by muse, mutect2
- FREM2 | c.1414G>A p.D472N | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779885596, COSV54842373; called by muse, mutect2, varscan2
- FSCB | c.1448C>A p.P483H | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.947); catalogued as COSV61218637; called by muse, mutect2, varscan2
- GABRA2 | c.1342G>T p.G448W | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.704); catalogued as COSV62916281; called by muse, mutect2, varscan2
- GALNT2 | c.1406G>A p.G469E | Missense Mutation (SNP) | VAF 51/316 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100795863; called by muse, mutect2, varscan2
- GBP5 | c.1432C>A p.Q478K | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.86); PolyPhen benign (0.053); catalogued as COSV100600151; called by muse, mutect2, varscan2
- GC | c.214G>T p.E72* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as COSV99910060; called by muse, mutect2, varscan2
- GCC1 | c.2328A>G p.*776Wext*82 | Nonstop Mutation (SNP) | VAF 25/82 reads (30%) | catalogued as COSV100365620; called by muse, mutect2, varscan2
- GGN | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.342); catalogued as COSV99287633; called by muse, mutect2, varscan2
- GHRHR | c.750G>T p.W250C | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100396734; called by muse, mutect2, varscan2
- GJA1 | c.586G>T p.V196L | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV99247217; called by muse, mutect2, varscan2
- GLI3 | c.3936G>T p.M1312I | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV101230000; called by muse, mutect2, varscan2
- GOLGA3 | c.2874A>T p.K958N | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.376); catalogued as COSV99212409; called by muse, mutect2, varscan2
- GPR137 | c.209C>A p.A70D | Missense Mutation (SNP) | VAF 40/274 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100464439; called by muse, mutect2, varscan2
- GPR39 | c.360C>A p.Y120* | Nonsense Mutation (SNP) | VAF 15/67 reads (22%) | catalogued as COSV100258301, COSV61429453; called by muse, mutect2, varscan2
- GPX5 | c.192C>G p.I64M | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.528); catalogued as COSV101297282; called by muse, mutect2, varscan2
- GPX6 | c.459G>A p.K153= | Splice Region (SNP) | VAF 11/77 reads (14%) | catalogued as COSV100724894; called by muse, mutect2, varscan2
- GREB1 | c.704C>T p.T235M | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs752977615, COSV52179947, COSV52182592; called by muse, varscan2
- GRIN3A | c.1802G>A p.G601E | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV62451769; called by muse, mutect2, varscan2
- GTF2F2 | c.491A>T p.E164V | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV100477309, COSV61239852; called by muse, mutect2, varscan2
- GTF3C1 | c.1886G>C p.R629P | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100649637; called by muse, mutect2
- GUCY2F | c.1832G>A p.G611D | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99485499; called by muse, mutect2, varscan2
- GZMH | c.565G>A p.G189R | Missense Mutation (SNP) | VAF 17/339 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99362021; called by muse, mutect2
- H4C2 | c.164C>T p.T55I | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.895); catalogued as rs149158970; called by muse, mutect2, varscan2
- HDX | c.1127G>T p.R376L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV99947897; called by muse, mutect2, varscan2
- HECW2 | c.391T>G p.F131V | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53672388, COSV99648442; called by muse, mutect2
- HIP1 | c.2365G>C p.A789P | Missense Mutation (SNP) | VAF 42/254 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as COSV100418078; called by muse, mutect2, varscan2
- HMCN1 | c.10038A>C p.K3346N | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.403); catalogued as COSV99634115; called by muse, mutect2, varscan2
- HSF1 | c.115C>A p.P39T | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.976); catalogued as COSV100266067; called by muse, mutect2
- IFNA8 | c.365G>C p.C122S | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101206925; called by muse, mutect2
- IGKV1D-43 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as rs1046854320; called by muse, mutect2
- IGSF10 | c.5773T>G p.S1925A | Missense Mutation (SNP) | VAF 15/205 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV99192474; called by muse, mutect2
- IGSF5 | c.1049-1G>A p.X350_splice | Splice Site (SNP) | VAF 16/85 reads (19%) | catalogued as COSV101012122; called by muse, mutect2, varscan2
- IKBKB | c.1775G>A p.R592Q | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.072); catalogued as COSV60599408; called by muse, mutect2
- IL21 | c.156T>G p.Y52* | Nonsense Mutation (SNP) | VAF 6/76 reads (8%) | catalogued as COSV52646934, COSV99144476; called by muse, mutect2
- IL27RA | c.340C>G p.L114V | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.202); catalogued as COSV99652342; called by muse, mutect2
- IL4R | c.707G>C p.G236A | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.171); catalogued as COSV99405315; called by muse, mutect2, varscan2
- INTS10 | c.836+1G>T p.X279_splice | Splice Site (SNP) | VAF 7/117 reads (6%) | catalogued as COSV101208726, COSV101208748; called by muse, mutect2
- ITM2C | c.179A>G p.Y60C | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100419662; called by muse, mutect2, varscan2
- KATNAL1 | c.247G>T p.D83Y | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV101017120; called by muse, mutect2, varscan2
- KCNQ3 | c.931C>A p.L311M | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV101196335; called by muse, mutect2
- KDM4C | c.1780G>T p.D594Y | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101185063; called by muse, mutect2
- KDM6A | c.2179G>T p.V727L | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV100938512; called by muse, mutect2
- KIAA1549 | c.2887A>G p.R963G | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99651692; called by muse, mutect2, varscan2
- KIF4A | c.2105G>A p.R702H | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs780288402, COSV65543709; called by muse, mutect2, varscan2
- KIFC1 | c.643G>C p.E215Q | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.706); catalogued as COSV100997131; called by muse, mutect2
- KLHL14 | c.1430-2A>G p.X477_splice | Splice Site (SNP) | VAF 20/184 reads (11%) | catalogued as COSV100839289, COSV63832484; called by muse, mutect2
- KLHL18 | c.1262G>A p.S421N | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99231227; called by muse, varscan2
- KRT3 | c.557A>C p.E186A | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as COSV100527227; called by muse, mutect2, varscan2
- KRT71 | c.813C>T p.A271= | Splice Region (SNP) | VAF 10/101 reads (10%) | catalogued as rs971529906, COSV99922328, COSV99922353; called by muse, mutect2, varscan2
- KRTAP11-1 | c.99T>G p.D33E | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.03); catalogued as rs756548637, COSV100190770; called by muse, mutect2, varscan2
- KRTAP19-3 | c.202C>A p.R68S | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.012); catalogued as COSV61854568; called by muse, mutect2
- KY | c.659C>T p.T220I | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as COSV101415027; called by muse, mutect2
- LAD1 | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.578); catalogued as COSV100943918; called by muse, mutect2, varscan2
- LMAN1L | c.342C>A p.Y114* | Nonsense Mutation (SNP) | VAF 13/99 reads (13%) | catalogued as COSV100547807; called by muse, mutect2, varscan2
- LRBA | c.6752C>A p.T2251N | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100841994; called by muse, mutect2, varscan2
- LRP1 | c.73A>T p.K25* | Nonsense Mutation (SNP) | VAF 14/164 reads (9%) | catalogued as rs1555179973, COSV99676854; called by muse, mutect2
- LRP3 | c.1582C>T p.Q528* | Nonsense Mutation (SNP) | VAF 5/24 reads (21%) | catalogued as COSV99472463; called by muse, mutect2, varscan2
- LRRC18 | c.451C>A p.L151I | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.397); catalogued as COSV99630406; called by muse, mutect2
- LRRC4C | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.853); catalogued as rs767793951, COSV53432956, COSV53438666; called by muse, mutect2, varscan2
- LRRIQ1 | c.3866G>T p.R1289I | Missense Mutation (SNP) | VAF 32/211 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.289); catalogued as COSV101280672; called by muse, mutect2, varscan2
- LRRTM3 | c.319G>T p.G107* | Nonsense Mutation (SNP) | VAF 13/133 reads (10%) | catalogued as COSV100791865, COSV63665800; called by muse, mutect2, varscan2
- LRRTM4 | c.1742C>A p.P581Q | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as COSV101299072, COSV101299177; called by muse, mutect2
- LRRTM4 | c.1502A>T p.N501I | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101297687; called by muse, mutect2, varscan2
- LRRTM4 | c.1279G>T p.A427S | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV69141353; called by muse, mutect2
- LVRN | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.8); PolyPhen benign (0.007); catalogued as COSV100773323, COSV100773621; called by muse, varscan2
- MAGEB6 | c.292C>A p.R98S | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV100983828; called by muse, mutect2, varscan2
- MAGEC1 | c.2950T>A p.S984T | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.154); catalogued as COSV99596283; called by muse, mutect2, varscan2
- MAGEE1 | c.2277G>T p.M759I | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.161); catalogued as COSV100819497, COSV63910497; called by muse, mutect2, varscan2
- MAGI1 | c.3248C>T p.T1083I (on ENST00000402939 / NM_001033057.2; = p.T1112I on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV100442655; called by muse, mutect2, varscan2
- MASP1 | c.643A>G p.T215A | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV99397567; called by muse, mutect2
- MBOAT1 | c.1255A>C p.K419Q | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100209116; called by muse, mutect2, varscan2
- MFSD9 | c.254-1G>T p.X85_splice | Splice Site (SNP) | VAF 10/80 reads (13%) | catalogued as COSV99302267; called by muse, mutect2, varscan2
- MGAM | c.2375G>C p.G792A | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); catalogued as COSV101527701; called by mutect2, varscan2
- MINK1 | c.2662G>A p.V888I | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.054); catalogued as COSV99545249; called by muse, mutect2
- MKI67 | c.4534A>T p.K1512* | Nonsense Mutation (SNP) | VAF 43/291 reads (15%) | catalogued as COSV100896898; called by muse, mutect2, varscan2
- MKRN3 | c.1198T>A p.C400S | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100091497; called by muse, mutect2, varscan2
- MLPH | c.836C>A p.P279H | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99222545; called by muse, mutect2
- MPHOSPH8 | c.640A>C p.K214Q | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); catalogued as COSV100825205; called by muse, mutect2
- MS4A13 | c.248T>A p.L83Q | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100981179; called by mutect2, varscan2
- MSANTD2 | c.89G>T p.G30V | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.11); catalogued as COSV53449263, COSV99515870; called by muse, mutect2, varscan2
- MTMR4 | c.739G>T p.D247Y | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100051340, COSV60201954; called by muse, mutect2, varscan2
- MTPAP | c.359A>T p.Q120L | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV99554260; called by muse, mutect2
- MUC17 | c.837A>C p.R279S | Missense Mutation (SNP) | VAF 18/242 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100074684; called by muse, mutect2
- MUC17 | c.4622C>A p.T1541N | Missense Mutation (SNP) | VAF 20/323 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as COSV100074685; called by muse, mutect2
- MXRA5 | c.4242G>T p.E1414D | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99478687; called by muse, mutect2, varscan2
- MYO15A | c.4136T>C p.L1379P | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as rs941346009, COSV99234033; called by muse, mutect2, varscan2
- MYO16 | c.550G>T p.G184* | Nonsense Mutation (SNP) | VAF 9/34 reads (26%) | catalogued as COSV99193811; called by muse, mutect2
- MYO3B | c.2164G>A p.D722N | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58712566; called by muse, mutect2, varscan2
- MYO9B | c.2038G>T p.V680L | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV101261485, COSV101261804; called by muse, mutect2, varscan2
- NAB1 | c.348G>C p.R116S | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.071); catalogued as COSV100493125; called by muse, mutect2
- NCAM2 | c.231del p.L78* | Frame Shift Del (DEL) | VAF 11/58 reads (19%) | catalogued as COSV99524153; called by mutect2, pindel, varscan2
- NCAN | c.1999G>T p.A667S | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as COSV99388081; called by muse, mutect2
- NCCRP1 | c.377C>T p.T126I | Missense Mutation (SNP) | VAF 23/210 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.428); catalogued as COSV100355867; called by muse, mutect2, varscan2
- NDST4 | c.1576G>T p.D526Y | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99996063, COSV99997499; called by muse, mutect2, varscan2
- NEB | c.11867C>T p.P3956L | Missense Mutation (SNP) | VAF 35/226 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99426541; called by muse, mutect2, varscan2
- NEB | c.10468G>T p.A3490S | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.02); catalogued as COSV99426546; called by muse, mutect2
- NFAT5 | c.1071C>A p.C357* | Nonsense Mutation (SNP) | VAF 15/99 reads (15%) | catalogued as COSV100591091, COSV63027891, COSV63029390; called by muse, mutect2, varscan2
- NFE2 | c.44A>T p.Q15L | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV100380831; called by muse, mutect2
- NLN | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV101114432; called by muse, mutect2
- NLN | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV101114434; called by muse, mutect2
- NMRK2 | c.167-1G>C p.X56_splice | Splice Site (SNP) | VAF 6/29 reads (21%) | catalogued as COSV99396488; called by muse, mutect2, varscan2
- NOL4 | c.1060C>G p.P354A | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52357422, COSV99307946; called by muse, mutect2, varscan2
- NOTCH3 | c.2544G>T p.Q848H | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); catalogued as COSV99658475; called by muse, mutect2, varscan2
- NOX3 | c.1220C>A p.A407E | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV50150775, COSV99343564; called by muse, mutect2, varscan2
- NRG3 | c.692C>G p.T231S | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV100932474; called by muse, mutect2
- NRIP1 | c.1429G>T p.D477Y | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.247); catalogued as COSV100012977; called by muse, mutect2, varscan2
- NXPE4 | c.1324T>A p.F442I (on ENST00000375478 / NM_001077639.2; = p.F158I on NM_017678.3) | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100970536, COSV64943759; called by muse, mutect2, varscan2
- OLFM4 | c.360G>A p.V120= | Splice Region (SNP) | VAF 9/41 reads (22%) | catalogued as COSV99524514; called by muse, mutect2, varscan2
- ONECUT2 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.585); catalogued as COSV101529810; called by muse, mutect2, varscan2
- OR2AK2 | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.622); catalogued as rs781537668, COSV100824267; called by muse, mutect2, varscan2
- OR2M7 | c.882C>A p.N294K | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV100522655; called by muse, mutect2, varscan2
- OR2T11 | c.140A>T p.Q47L | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as COSV100424921; called by muse, mutect2
- OR2T27 | c.370G>T p.V124L | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as COSV100788345; called by mutect2, varscan2
- OR2T27 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.02); catalogued as COSV61281368; called by muse, varscan2
- OR2T8 | c.826T>G p.Y276D | Missense Mutation (SNP) | VAF 20/226 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100178427; called by muse, mutect2
- OR4D6 | c.550G>T p.V184L | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.116); catalogued as COSV100271800; called by muse, mutect2, varscan2
- OR4Q3 | c.133G>T p.A45S | Missense Mutation (SNP) | VAF 11/275 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.318); catalogued as COSV100057291; called by muse, mutect2
- OR51T1 | c.621C>A p.Y207* | Nonsense Mutation (SNP) | VAF 7/103 reads (7%) | catalogued as COSV100434457; called by muse, mutect2
- OR51T1 | c.622C>A p.L208M | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as COSV59026812; called by muse, mutect2
- OR5B12 | c.332del p.F111Sfs*24 | Frame Shift Del (DEL) | VAF 20/109 reads (18%) | catalogued as rs1306029861; called by mutect2, pindel, varscan2
- OR5F1 | c.908A>T p.N303I | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV99558854; called by muse, mutect2
- OR5F1 | c.571G>T p.D191Y | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53547531; called by muse, mutect2, varscan2
- OR5J2 | c.368A>C p.Y123S | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs1182709795, COSV100399199; called by muse, mutect2, varscan2
- OR5M11 | c.490del p.R164Afs*2 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | catalogued as COSV73141636; called by mutect2, pindel, varscan2
- OR6B1 | c.282C>A p.F94L | Missense Mutation (SNP) | VAF 11/192 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as COSV101281663; called by muse, mutect2
- OR8H2 | c.498G>T p.L166F | Missense Mutation (SNP) | VAF 41/242 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV57943391; called by muse, mutect2, varscan2
- OR8H3 | c.671C>A p.T224N | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.25); catalogued as COSV100539121; called by muse, mutect2
- OSBP2 | c.1159C>T p.R387W | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs922992144, COSV60248354; called by muse, mutect2, varscan2
- OTOL1 | c.425A>T p.Q142L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV100020186; called by mutect2, varscan2
- OVGP1 | c.1690C>A p.P564T | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV63860058; called by muse, mutect2
- PACSIN3 | c.952C>T p.R318W | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as rs113148315; called by muse, mutect2, varscan2
- PAPPA2 | c.4967C>A p.P1656H | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100868483; called by muse, mutect2, varscan2
- PCDH11X | c.440C>T p.S147L | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100014247; called by muse, mutect2, varscan2
- PCDHB13 | c.2344G>T p.E782* | Nonsense Mutation (SNP) | VAF 26/88 reads (30%) | catalogued as rs138168445, COSV99507773; called by muse, mutect2, varscan2
- PCDHB7 | c.1892G>A p.S631N | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.72); catalogued as COSV50806038; called by muse, mutect2
- PCDHGB2 | c.323C>A p.T108N | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV99544479; called by muse, mutect2, varscan2
- PCSK5 | c.4347C>A p.C1449* | Nonsense Mutation (SNP) | VAF 16/226 reads (7%) | catalogued as COSV101377681; called by muse, mutect2
- PEAK1 | c.4129G>T p.V1377F | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV100433361; called by muse, mutect2
- PIGU | c.1215C>G p.Y405* | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | catalogued as COSV99466785; called by muse, mutect2
- PLA1A | c.596C>A p.A199D | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99846015; called by muse, mutect2
- PLAG1 | c.433G>C p.A145P | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100388157, COSV57609038; called by muse, mutect2
- PLEK | c.516G>T p.R172S | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.643); catalogued as COSV99311179; called by muse, mutect2, varscan2
- PLRG1 | c.1369G>T p.G457W | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100123226; called by muse, mutect2, varscan2
- PLXNB3 | c.4834-2A>T p.X1612_splice | Splice Site (SNP) | VAF 3/9 reads (33%) | catalogued as COSV100737783; called by muse, mutect2
- PLXNC1 | c.3231G>T p.K1077N | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs372867067; called by muse, mutect2, varscan2
- PMPCA | c.1419G>T p.K473N | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.097); catalogued as COSV100867823; called by muse, mutect2, varscan2
- PNLIP | c.284T>C p.I95T | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.076); catalogued as rs1199156517; called by muse, mutect2
- POLN | c.1229A>T p.D410V | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV101242701; called by muse, mutect2
- POLQ | c.2524G>T p.A842S | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.71); PolyPhen benign (0.018); catalogued as COSV99952720; called by muse, mutect2
- POLR3B | c.499G>A p.G167S | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99943775; called by muse, mutect2, varscan2
- PPFIA2 | c.3557G>T p.S1186I | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as COSV100334787; called by muse, mutect2, varscan2
- PROKR1 | c.935C>A p.T312N | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV100375680; called by muse, varscan2
- PROX1 | c.2137G>T p.V713F | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV99799130; called by muse, mutect2, varscan2
- PRSS58 | c.377C>A p.T126N | Missense Mutation (SNP) | VAF 9/181 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as rs750785269, COSV101616157; called by muse, mutect2
- PSD3 | c.2367T>A p.S789R (on ENST00000440756; = p.S788R on NM_015310.4) | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.166); catalogued as rs1289063494, COSV99676627; called by muse, mutect2
- PSD4 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs1018074830, COSV99831397; called by muse, mutect2, varscan2
- PSMA1 | c.172G>T p.A58S | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV101123694; called by muse, mutect2
- PTK7 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0.164); catalogued as rs148069775, COSV57847380; called by muse, mutect2, varscan2
- PTPN4 | c.145G>T p.D49Y | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as COSV99751089; called by muse, mutect2, varscan2
- PTPN5 | c.226G>T p.G76C | Missense Mutation (SNP) | VAF 19/187 reads (10%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV100659962; called by muse, mutect2, varscan2
- PTPRD | c.4326G>A p.M1442I | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100646186; called by muse, mutect2, varscan2
- PTPRM | c.2410G>A p.E804K | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs569455729, COSV59862508; called by muse, mutect2
- PTPRS | c.5191G>C p.E1731Q | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99511974; called by muse, mutect2
- PTX3 | c.592C>G p.P198A | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV55821273, COSV99904967; called by muse, mutect2, varscan2
- PYGL | c.79G>C p.E27Q | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.24); catalogued as rs376771385; called by muse, mutect2, varscan2
- QTRT2 | c.662G>T p.G221V | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99847009; called by muse, mutect2
- RAB3GAP1 | c.1354C>A p.P452T | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99921600; called by muse, mutect2, varscan2
- RAB3GAP2 | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100741412; called by muse, mutect2
- RAB3IP | c.1380G>C p.L460F (on ENST00000550536 / NM_175623.4; = p.L444F on NM_022456.5) | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99922991; called by muse, mutect2
- RAD54B | c.2255C>G p.S752C | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100279657, COSV100280109; called by muse, mutect2, varscan2
- RALGDS | c.2329C>T p.R777C | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs777108342, COSV100924538; called by muse, mutect2, varscan2
- RAPGEF2 | c.1113G>T p.R371S | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.417); catalogued as COSV100031531; called by muse, mutect2
- RB1CC1 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99212624; called by muse, mutect2, varscan2
- RGS12 | c.3733A>C p.S1245R | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.107); catalogued as COSV100123240; called by muse, mutect2, varscan2
- RLBP1 | c.190C>T p.R64* | Nonsense Mutation (SNP) | VAF 19/115 reads (17%) | catalogued as COSV51529467; called by muse, mutect2, varscan2
- RNF168 | c.311A>G p.Y104C | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs755261571, COSV100535088; called by muse, mutect2, varscan2
- RNF40 | c.407C>A p.T136N | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV100222283; called by muse, mutect2
- RP1L1 | c.4166C>A p.A1389D | Missense Mutation (SNP) | VAF 19/342 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1298179320, COSV101223526; called by muse, mutect2
- RPAP1 | c.1806G>T p.W602C | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775522329, COSV100427299; called by muse, mutect2, varscan2
- RPS6KA6 | c.1848G>T p.L616F | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99425268; called by muse, mutect2
- RSAD2 | c.260G>A p.C87Y | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101150004; called by muse, mutect2
- RUSC2 | c.3953G>A p.R1318Q | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1341133557, COSV100770830; called by muse, mutect2
- RXFP2 | c.2237G>A p.G746E | Missense Mutation (SNP) | VAF 52/235 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.012); catalogued as COSV53635503; called by muse, mutect2, varscan2
- RYR2 | c.3994A>C p.N1332H | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100772217; called by muse, mutect2
- RYR2 | c.5320G>T p.E1774* | Nonsense Mutation (SNP) | VAF 26/135 reads (19%) | catalogued as COSV100772219; called by muse, mutect2, varscan2
- S100A16 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV100905897; called by muse, mutect2
- SALL3 | c.3755del p.P1252Lfs*52 | Frame Shift Del (DEL) | VAF 20/164 reads (12%) | catalogued as COSV73306070; called by mutect2, varscan2
- SALL4 | c.1300C>A p.Q434K | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV99409790; called by muse, mutect2, varscan2
- SCML4 | c.429C>G p.H143Q | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as COSV100940425; called by muse, mutect2, varscan2
- SCN11A | c.1772C>A p.T591N | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100181359, COSV100182202; called by muse, mutect2, varscan2
- SCN7A | c.4110G>T p.M1370I | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV101313332; called by muse, mutect2, varscan2
- SDK1 | c.977G>T p.S326I | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.074); catalogued as COSV67367911; called by muse, mutect2
- SEC16B | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as COSV100381849; called by muse, mutect2
- SEC16B | c.106G>C p.V36L | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV100381850, COSV57624531; called by muse, mutect2, varscan2
- SEC24C | c.2285G>T p.R762L | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100227103; called by muse, mutect2, varscan2
- SEMA3D | c.1759A>T p.I587F | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.018); catalogued as COSV99407211; called by muse, mutect2, varscan2
- SERBP1 | c.1141C>T p.R381C (on ENST00000370995 / NM_001018067.2; = p.R360C on NM_015640.4) | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs781357375, COSV63413187; called by muse, mutect2, varscan2
- SERPINA11 | c.484G>C p.G162R | Missense Mutation (SNP) | VAF 17/268 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.658); catalogued as COSV100594140; called by muse, mutect2
- SERPINA5 | c.1153A>C p.N385H | Missense Mutation (SNP) | VAF 61/455 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100291770; called by muse, mutect2, varscan2
- SETX | c.946C>G p.Q316E | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56384562; called by muse, mutect2
- SFTPD | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.75); PolyPhen benign (0.017); catalogued as COSV100954554; called by muse, mutect2, varscan2
- SLC12A1 | c.371C>A p.P124H | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV57708002; called by muse, mutect2, varscan2
- SLC13A1 | c.281G>A p.C94Y | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99521348; called by muse, mutect2, varscan2
- SLC35B2 | c.958G>C p.E320Q | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.74); PolyPhen benign (0.006); catalogued as rs190246649, COSV99241350; called by muse, mutect2, varscan2
- SLC44A5 | c.2053G>A p.D685N | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100902414; called by muse, mutect2, varscan2
- SLC6A12 | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100675197; called by muse, mutect2, varscan2
- SLIT1 | c.3964G>A p.E1322K | Missense Mutation (SNP) | VAF 12/193 reads (6%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.996); catalogued as rs1268863455, COSV56600812; called by muse, mutect2
- SLIT2 | c.1364C>A p.A455D | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56599211, COSV99886428; called by muse, mutect2
- SLIT2 | c.4034C>A p.T1345K | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.045); catalogued as rs1414213710, COSV99886447; called by muse, mutect2, varscan2
- SLIT3 | c.2927A>T p.H976L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100269280; called by muse, mutect2, varscan2
- SLITRK2 | c.830A>T p.H277L | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as COSV100158108; called by muse, mutect2, varscan2
- SMARCA4 | c.2753T>G p.L918R | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100759020; called by muse, mutect2, varscan2
- SMPDL3B | c.834C>G p.H278Q | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.21); catalogued as COSV100874605; called by muse, mutect2, varscan2
- SMYD1 | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1272258930, COSV101352396, COSV101352401; called by muse, mutect2
- SNRPE | c.208T>A p.S70T | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV100919304; called by muse, mutect2, varscan2
- SORCS1 | c.2820C>G p.S940R | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV99549222; called by mutect2, varscan2
- SOX9 | c.551A>T p.N184I | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); catalogued as COSV99818675; called by muse, mutect2, varscan2
- SPAG5 | c.3230G>T p.R1077L | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV99881946; called by muse, mutect2, varscan2
- SPHKAP | c.853C>T p.R285* | Nonsense Mutation (SNP) | VAF 18/252 reads (7%) | catalogued as rs974637140, COSV60887126; called by muse, mutect2
- SPIB | c.136G>C p.D46H | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.088); catalogued as COSV99570088, COSV99570100; called by muse, mutect2, varscan2
- SPTB | c.4704G>C p.R1568S | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as COSV101072375; called by muse, mutect2
- SRD5A2 | c.587G>A p.G196D | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM113475, COSV99252559; called by mutect2, varscan2
- SRRM2 | c.2385G>T p.R795S | Missense Mutation (SNP) | VAF 26/378 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.086); catalogued as COSV100071308; called by muse, mutect2
- ST8SIA4 | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 10/93 reads (11%) | PolyPhen benign (0.099); catalogued as COSV51517628; called by muse, mutect2, varscan2
- ST8SIA6 | c.442G>T p.V148F | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as COSV66469670; called by muse, mutect2
- STARD3NL | c.258G>C p.K86N | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV99151606; called by mutect2, varscan2
- STEAP2 | c.1135A>G p.I379V | Missense Mutation (SNP) | VAF 43/236 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.401); catalogued as rs140360438; called by muse, mutect2, varscan2
- STK33 | c.280G>T p.G94C | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.72); catalogued as COSV100174388; called by muse, mutect2
- SUSD6 | c.590A>G p.Q197R | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.15); catalogued as COSV100713493; called by muse, mutect2, varscan2
- SYCP1 | c.1863G>C p.E621D | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1217370529, COSV101051113; called by muse, mutect2
- SYNE1 | c.731C>A p.T244N (on ENST00000367255 / NM_182961.4; = p.T251N on NM_033071.3) | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.084); catalogued as rs1362825272, COSV54988541, COSV99575117; called by muse, mutect2, varscan2
- TAF5L | c.508G>C p.D170H | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV99273549; called by muse, mutect2
- TAFA1 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.994); catalogued as COSV101524520; called by muse, mutect2, varscan2
- TAOK3 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1273576411, COSV101183691; called by muse, mutect2
- TASP1 | c.875G>C p.G292A | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100534755; called by muse, mutect2, varscan2
- TBC1D17 | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.409); catalogued as rs749223360, COSV55579293; called by muse, mutect2, varscan2
- TBXT | c.496T>G p.Y166D | Missense Mutation (SNP) | VAF 47/322 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99752816; called by muse, mutect2, varscan2
- TCF20 | c.3695C>T p.P1232L | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.617); catalogued as COSV100166846; called by muse, mutect2, varscan2
- TCN1 | c.1158C>G p.I386M | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV57252585, COSV99953413; called by muse, mutect2, varscan2
- TDRD6 | c.4711G>A p.G1571R | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV100288148; called by muse, mutect2, varscan2
- TDRD6 | c.5729C>A p.P1910H | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV100288149; called by muse, mutect2, varscan2
- TDRD6 | c.5989G>T p.E1997* | Nonsense Mutation (SNP) | VAF 12/98 reads (12%) | catalogued as COSV100287793; called by muse, mutect2, varscan2
- TECTB | c.521T>C p.V174A | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.135); catalogued as rs771587792, COSV101027763; called by mutect2, varscan2
- TEPSIN | c.739T>A p.L247M | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.02); catalogued as COSV100329903; called by muse, mutect2
- TEX14 | c.376A>T p.K126* | Nonsense Mutation (SNP) | VAF 6/117 reads (5%) | catalogued as COSV99543225; called by muse, mutect2
- TEX37 | c.485A>G p.H162R | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.001); catalogued as rs569946183, COSV100304661; called by muse, mutect2, varscan2
- THSD1 | c.2279G>C p.R760P | Missense Mutation (SNP) | VAF 49/190 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as rs200293227, COSV99319024; called by muse, mutect2, varscan2
- THSD1 | c.254C>A p.T85K | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.802); catalogued as COSV99319025; called by muse, mutect2
- TIAM1 | c.1810-1G>C p.X604_splice | Splice Site (SNP) | VAF 14/54 reads (26%) | catalogued as COSV54539540; called by muse, mutect2, varscan2
- TMC5 | c.146G>T p.G49V | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.023); catalogued as COSV66867459; called by muse, mutect2, varscan2
- TMEM202 | c.347A>T p.Q116L | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as COSV100499234; called by muse, mutect2, varscan2
- TMEM217 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV100362663; called by muse, mutect2, varscan2
- TNN | c.92C>A p.P31H | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99512727; called by muse, mutect2, varscan2
- TNR | c.1505C>T p.T502I | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99690980; called by muse, mutect2, varscan2
- TNR | c.160T>A p.Y54N | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.079); catalogued as COSV99690984; called by muse, mutect2
- TONSL | c.3488G>A p.R1163H | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs782299928, COSV68049479; called by muse, mutect2
- TRAF3 | c.1111G>T p.A371S | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV100693706; called by muse, mutect2, varscan2
- TRGV4 | c.175G>C p.G59R | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs768071389; called by muse, mutect2, varscan2
- TROAP | c.1164G>T p.W388C | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1190743092, COSV99226978; called by muse, mutect2, varscan2
- TRPC4 | c.1501C>A p.H501N | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100157641; called by muse, mutect2, varscan2
- TSHZ2 | c.2770C>T p.P924S | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100296585; called by muse, mutect2
- TSHZ3 | c.1259A>T p.K420I | Missense Mutation (SNP) | VAF 59/200 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99552432; called by muse, mutect2, varscan2
- TSN | c.67-2A>C p.X23_splice | Splice Site (SNP) | VAF 8/68 reads (12%) | catalogued as COSV101067574; called by muse, mutect2, varscan2
- TTC21B | c.3357C>G p.H1119Q | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV54632333, COSV99692114; called by muse, mutect2, varscan2
- TTN | c.59813T>A p.L19938Q (on ENST00000591111; = p.L12514Q on NM_003319.4) | Missense Mutation (SNP) | VAF 9/133 reads (7%) | PolyPhen probably damaging (0.982); catalogued as COSV100625397; called by muse, mutect2
- TTN | c.31045C>A p.P10349T (on ENST00000591111; = p.P9422T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/56 reads (18%) | PolyPhen probably damaging (0.991); catalogued as COSV100625403; called by muse, mutect2, varscan2
- TTN | c.22213C>A p.Q7405K (on ENST00000591111; = p.Q6478K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/31 reads (16%) | PolyPhen benign (0.121); catalogued as COSV100625406, COSV60259449; called by muse, mutect2, varscan2
- TTN | c.14503G>T p.E4835* (on ENST00000591111; = p.E3908* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 27/179 reads (15%) | catalogued as COSV100625408, COSV100627039; called by muse, mutect2, varscan2
- TYK2 | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 10/63 reads (16%) | catalogued as COSV53390454, COSV99315216; called by muse, mutect2, varscan2
- TYK2 | c.162G>T p.E54D | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99315222; called by muse, mutect2, varscan2
- TYRP1 | c.1193C>T p.P398L | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV101141436; called by muse, mutect2, varscan2
- UBAP2L | c.1787C>A p.S596Y | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV99672034; called by muse, mutect2
- UBQLNL | c.211G>T p.V71L | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100975184; called by muse, mutect2
- UGT2A3 | c.743T>G p.V248G | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV99280158; called by muse, mutect2
- UGT2B7 | c.728C>A p.P243H | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as COSV100535292; called by muse, mutect2, varscan2
- UNC5D | c.337G>T p.E113* | Nonsense Mutation (SNP) | VAF 16/234 reads (7%) | catalogued as COSV99777898; called by muse, mutect2
- USP26 | c.2518G>T p.G840C | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100896731; called by muse, mutect2, varscan2
- USP31 | c.2138G>T p.C713F | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99565680; called by muse, varscan2
- UTRN | c.925A>G p.M309V | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.98); PolyPhen benign (0.007); catalogued as COSV100840310; called by muse, mutect2, varscan2
- VN1R4 | c.641A>T p.Q214L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.214); catalogued as COSV100237552; called by muse, mutect2, varscan2
- VPS13A | c.7267G>T p.E2423* | Nonsense Mutation (SNP) | VAF 6/124 reads (5%) | catalogued as COSV100653292; called by muse, mutect2
- VPS13D | c.12704G>T p.G4235V | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99167973; called by muse, mutect2, varscan2
- VPS50 | c.1627G>T p.G543W | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100005146; called by muse, mutect2, varscan2
- VWA8 | c.338G>T p.G113V | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99864863; called by muse, mutect2
- WBP2NL | c.465T>A p.Y155* | Nonsense Mutation (SNP) | VAF 21/154 reads (14%) | catalogued as rs1482213374, COSV100173897; called by muse, mutect2, varscan2
- WDPCP | c.1988G>A p.G663E | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1464624316, COSV55415706, COSV99706457; called by muse, mutect2, varscan2
- WDR24 | c.1721A>T p.Q574L (on ENST00000248142; = p.Q444L on NM_032259.4) | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.147); catalogued as COSV99555938; called by muse, mutect2, varscan2
- WDR59 | c.550G>T p.V184L | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as COSV100049630; called by muse, mutect2, varscan2
- WDR72 | c.572C>T p.S191L | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs771876577, COSV100854956; called by muse, mutect2, varscan2
- WNK2 | c.4879G>A p.G1627R (on ENST00000297954 / NM_001282394.1; = p.G1590R on NM_006648.3) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as COSV99944078; called by muse, mutect2
- XAB2 | c.1100A>T p.H367L | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100601835; called by muse, mutect2, varscan2
- XIRP2 | c.7481C>T p.S2494F (on ENST00000628543; = p.S2669F on NM_152381.6) | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.233); catalogued as rs1331928403, COSV99745014; called by muse, mutect2, varscan2
- Z83844.2 | c.1180G>T p.V394F | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100379321, COSV100379412; called by muse, mutect2, varscan2
- ZBTB16 | c.884T>A p.L295Q | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100251958; called by muse, mutect2, varscan2
- ZFHX4 | c.5029G>T p.D1677Y | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as COSV51496043, COSV99266404; called by muse, mutect2
- ZFYVE16 | c.2735C>T p.T912I | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.194); catalogued as COSV100566603; called by muse, mutect2
- ZFYVE28 | c.725G>C p.G242A | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52116385, COSV99343538; called by muse, mutect2
- ZIC4 | c.419C>T p.T140I | Missense Mutation (SNP) | VAF 18/177 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as rs867896521, COSV101268103; called by muse, mutect2, varscan2
- ZNF121 | c.635G>T p.R212L | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs142823332, COSV100248245, COSV57551165; called by muse, mutect2, varscan2
- ZNF2 | c.151G>T p.V51L | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs755355546, COSV99728644; called by muse, mutect2, varscan2
- ZNF202 | c.1711G>T p.G571W | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100279127, COSV60246778; called by muse, mutect2, varscan2
- ZNF222 | c.1010G>T p.G337V | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99496533; called by muse, mutect2
- ZNF32 | c.548A>C p.H183P | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as COSV100986510; called by muse, mutect2, varscan2
- ZNF329 | c.1519A>T p.R507W | Missense Mutation (SNP) | VAF 17/229 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100798808; called by muse, mutect2
- ZNF33A | c.1858A>G p.K620E (on ENST00000458705 / NM_006974.3; = p.K621E on NM_006954.2) | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1490366353, COSV100276113; called by muse, mutect2
- ZNF423 | c.1353T>A p.C451* (on ENST00000563137 / NM_001379286.1; = p.C443* on NM_015069.4) | Nonsense Mutation (SNP) | VAF 12/82 reads (15%) | catalogued as rs1555515697, COSV99283279; called by muse, mutect2, varscan2
- ZNF536 | c.2118G>C p.Q706H | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100835668; called by muse, mutect2, varscan2
- ZNF746 | c.578A>T p.E193V | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV100502549, COSV61406142; called by muse, mutect2, varscan2
- ZNF804B | c.1504G>T p.G502C | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100305471; called by muse, mutect2, varscan2
- ZNF804B | c.3643C>A p.Q1215K | Missense Mutation (SNP) | VAF 11/150 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs886244115, COSV100305474; called by muse, mutect2
- ZNF91 | c.1487G>A p.G496D | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV100323341; called by muse, mutect2, varscan2
- ZRANB1 | c.938A>G p.Y313C | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.605); catalogued as COSV100669307; called by muse, mutect2, varscan2
- ACAN | c.1663dup p.V555Gfs*23 | Frame Shift Ins (INS) | VAF 12/116 reads (10%) | called by mutect2, pindel
- AGBL2 | c.1003G>T p.G335W | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANGPT1 | c.409C>A p.Q137K | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2
- BLK | c.77T>A p.L26Q | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.007); called by muse, mutect2
- CD46 | c.1159_1162dup p.K388Sfs*20 | Frame Shift Ins (INS) | VAF 7/55 reads (13%) | called by mutect2, pindel, varscan2
- COL19A1 | c.374A>T p.Q125L | Missense Mutation (SNP) | VAF 4/93 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2
- ERCC6L | c.3685dup p.I1229Nfs*7 | Frame Shift Ins (INS) | VAF 9/35 reads (26%) | called by mutect2, pindel, varscan2
- FAT1 | c.9247del p.T3083Pfs*33 | Frame Shift Del (DEL) | VAF 7/44 reads (16%) | called by mutect2, pindel, varscan2
- FCGBP | c.3080C>T p.A1027V | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.958); called by muse, mutect2
- GABRA2 | c.1177dup p.T393Nfs*14 | Frame Shift Ins (INS) | VAF 23/170 reads (14%) | called by mutect2, pindel, varscan2
- GAS2L2 | c.2041C>A p.P681T | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.186); called by muse, mutect2
- GOLPH3 | c.729_730del p.H244Cfs*18 | Frame Shift Del (DEL) | VAF 14/99 reads (14%) | called by mutect2, pindel, varscan2
- HIVEP3 | c.1815del p.E605Dfs*32 | Frame Shift Del (DEL) | VAF 17/119 reads (14%) | called by mutect2, pindel, varscan2
- HYDIN | c.400G>C p.V134L | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.243); called by muse, mutect2
- IDO1 | c.758G>A p.W253* | Nonsense Mutation (SNP) | VAF 4/49 reads (8%) | called by muse, mutect2
- IGKV1-27 | c.269G>T p.G90V | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- IGLV3-32 | c.123G>C p.Q41H | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2
- KDSR | c.605dup p.M202Ifs*7 | Frame Shift Ins (INS) | VAF 22/135 reads (16%) | called by mutect2, pindel, varscan2
- KEL | c.1534G>T p.V512F | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.23); called by muse, mutect2
- KLHL28 | c.159dup p.A54Cfs*17 | Frame Shift Ins (INS) | VAF 11/104 reads (11%) | called by mutect2, pindel, varscan2
- MAGEA4 | c.23dup p.H9Afs*5 | Frame Shift Ins (INS) | VAF 13/51 reads (25%) | called by mutect2, pindel, varscan2
- MAGEB6B | c.491C>G p.S164* | Nonsense Mutation (SNP) | VAF 21/49 reads (43%) | called by muse, mutect2, varscan2
- MAP3K11 | c.2052_2053del p.P685Lfs*46 | Frame Shift Del (DEL) | VAF 10/74 reads (14%) | called by pindel, varscan2
- MERTK | c.2878del p.E960Rfs*39 | Frame Shift Del (DEL) | VAF 8/68 reads (12%) | called by mutect2, pindel, varscan2
- NKTR | c.2449C>T p.Q817* | Nonsense Mutation (SNP) | VAF 7/88 reads (8%) | called by muse, mutect2
- OR2M2 | c.206T>A p.M69K | Missense Mutation (SNP) | VAF 22/510 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2
- OR2M2 | c.207G>T p.M69I | Missense Mutation (SNP) | VAF 22/514 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.045); called by muse, mutect2
- OR8G2P | c.852G>T p.M284I | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.041); called by mutect2, varscan2
- PCDHA4 | c.826del p.D276Tfs*14 | Frame Shift Del (DEL) | VAF 10/84 reads (12%) | called by mutect2, pindel, varscan2
- PEG3 | c.1289_1291delinsTT p.S430Ifs*2 | Frame Shift Del (DEL) | VAF 28/194 reads (14%) | called by pindel, varscan2*
- PIK3R2 | c.1368G>C p.K456N | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); called by muse, mutect2
- PPP1R3A | c.2869del p.T957Qfs*26 | Frame Shift Del (DEL) | VAF 7/92 reads (8%) | called by mutect2, pindel*
- PPP1R9A | c.971del p.P324Lfs*21 | Frame Shift Del (DEL) | VAF 9/60 reads (15%) | called by mutect2, pindel, varscan2
- PPP1R9A | c.2735G>C p.G912A | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); called by muse, mutect2
- PRAMEF17 | c.286A>T p.R96W | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- PRDM9 | c.770G>T p.G257V | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SAP130 | c.2539G>A p.E847K | Missense Mutation (SNP) | VAF 10/159 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- SERPINA10 | c.1043T>A p.M348K | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); called by muse, mutect2
- SI | c.3595G>T p.G1199C | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SIPA1L2 | c.1895_1918del p.P632_D639del | In Frame Del (DEL) | VAF 14/102 reads (14%) | called by mutect2, pindel
- TFEC | c.980del p.P327Lfs*24 | Frame Shift Del (DEL) | VAF 20/126 reads (16%) | called by mutect2, pindel, varscan2
- TSHZ3 | c.304G>T p.V102F | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2
- TTN | c.86537G>C p.S28846T (on ENST00000591111; = p.S21422T on NM_003319.4) | Missense Mutation (SNP) | VAF 3/42 reads (7%) | PolyPhen possibly damaging (0.652); called by muse, mutect2
- ULK4 | c.2194-1G>T p.X732_splice | Splice Site (SNP) | VAF 6/45 reads (13%) | called by muse, mutect2, varscan2
- ABLIM1 | c.27G>A p.E9= | Silent (SNP) | VAF 4/69 reads (6%) | called by muse, mutect2
- AIPL1 | c.789C>T p.I263= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as rs937436842, COSV51507034; called by muse, mutect2, varscan2
- ALDH3B2 | c.840C>T p.P280= | Silent (SNP) | VAF 22/182 reads (12%) | catalogued as COSV100824104; called by muse, mutect2, varscan2
- ALG10 | c.144C>T p.Y48= | Silent (SNP) | VAF 24/299 reads (8%) | catalogued as rs770410481, COSV99848298; called by muse, mutect2
- APLNR | c.1044G>A p.S348= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as rs769817882, COSV99951537, COSV99951604; called by muse, mutect2, varscan2
- ARHGAP32 | c.1680G>A p.L560= (on ENST00000310343 / NM_001378025.1; = p.L211= on NM_014715.4) | Silent (SNP) | VAF 18/95 reads (19%) | catalogued as COSV100088811; called by muse, mutect2, varscan2
- ARHGAP44 | c.372G>T p.L124= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV99311353; called by muse, mutect2
- ATP10A | c.4326C>G p.S1442= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV100791436; called by mutect2, varscan2
- ATP2B3 | c.2613C>G p.A871= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV99685496; called by muse, mutect2, varscan2
- BMP2K | c.438A>G p.L146= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV100621897; called by muse, mutect2, varscan2
- CACNG7 | c.150C>T p.V50= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV55812873; called by muse, mutect2
- CANT1 | c.210C>T p.P70= | Silent (SNP) | VAF 31/127 reads (24%) | catalogued as rs758216649, COSV100185352; called by muse, mutect2, varscan2
- CASKIN1 | c.1194G>C p.R398= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV100624360; called by muse, mutect2, varscan2
- CCDC39 | c.1230G>A p.Q410= | Silent (SNP) | VAF 8/146 reads (5%) | called by muse, mutect2
- CDH20 | c.1257C>G p.T419= | Silent (SNP) | VAF 34/228 reads (15%) | catalogued as COSV99406277; called by muse, mutect2, varscan2
- CEP97 | c.216G>T p.R72= | Silent (SNP) | VAF 8/147 reads (5%) | catalogued as COSV100512020; called by muse, mutect2
- CFAP221 | c.877C>A p.R293= | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as COSV54654594, COSV99733007; called by muse, mutect2, varscan2
- CFAP69 | c.1761A>G p.T587= | Silent (SNP) | VAF 26/108 reads (24%) | catalogued as rs1275010812, COSV100290370; called by muse, mutect2, varscan2
- CLDN5 | c.609G>C p.P203= (on ENST00000618236 / NM_001363066.2; = p.P288= on NM_003277.4) | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV99596944; called by muse, mutect2
- CLEC4A | c.120C>T p.T40= | Silent (SNP) | VAF 35/78 reads (45%) | catalogued as rs753939545, COSV57562764; called by muse, mutect2, varscan2
- CLUL1 | c.1131G>A p.K377= | Silent (SNP) | VAF 12/116 reads (10%) | catalogued as rs776330051, COSV100621030; called by muse, mutect2, varscan2
- COL1A1 | c.852T>A p.G284= | Silent (SNP) | VAF 37/349 reads (11%) | catalogued as COSV99867953; called by muse, mutect2, varscan2
- COL2A1 | c.471C>A p.T157= | Silent (SNP) | VAF 5/76 reads (7%) | catalogued as rs996191339; called by muse, mutect2
- COPB1 | c.1032A>C p.A344= | Silent (SNP) | VAF 8/126 reads (6%) | catalogued as COSV51449500, COSV99999840; called by muse, mutect2
- CSMD2 | c.3201C>G p.P1067= | Silent (SNP) | VAF 78/255 reads (31%) | catalogued as COSV99591152, COSV99593968; called by muse, mutect2, varscan2
- CUBN | c.9414G>A p.Q3138= | Silent (SNP) | VAF 12/146 reads (8%) | catalogued as COSV64729116; called by muse, mutect2
- DDX52 | c.432G>T p.R144= | Silent (SNP) | VAF 15/131 reads (11%) | called by muse, mutect2, varscan2
- ECT2L | c.558G>C p.L186= | Silent (SNP) | VAF 12/93 reads (13%) | catalogued as COSV100872146, COSV62884412; called by muse, mutect2, varscan2
- EFNB2 | c.699A>G p.S233= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as COSV99808914; called by muse, mutect2, varscan2
- ELOA2 | c.333C>A p.G111= | Silent (SNP) | VAF 13/102 reads (13%) | catalogued as COSV99797634; called by muse, mutect2, varscan2
- EML2 | c.234G>T p.G78= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV99840102, COSV99840344; called by mutect2, varscan2
- ENTPD6 | c.1125G>A p.K375= | Silent (SNP) | VAF 21/143 reads (15%) | catalogued as rs1451382013, COSV100737151; called by muse, mutect2, varscan2
- EP400 | c.8274A>G p.P2758= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs778724527, COSV100201994; called by muse, mutect2, varscan2
- FAM47A | c.1914C>A p.T638= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV100650021; called by muse, mutect2, varscan2
- FAR2 | c.822C>T p.D274= | Silent (SNP) | VAF 13/177 reads (7%) | catalogued as rs755470567, COSV51723307; called by muse, mutect2
- FCGBP | c.657C>T p.P219= | Silent (SNP) | VAF 18/109 reads (17%) | catalogued as rs768975994; called by muse, mutect2, varscan2
- FER1L5 | c.5700C>T p.P1900= (on ENST00000623019; = p.P1864= on NM_001293083.2) | Silent (SNP) | VAF 19/137 reads (14%) | catalogued as COSV99383559; called by muse, mutect2, varscan2
- FGA | c.1797G>A p.K599= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as COSV100120615; called by muse, mutect2, varscan2
- FSCB | c.2085C>A p.T695= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV100469716, COSV61218191; called by muse, mutect2, varscan2
- GALNT15 | c.1440G>T p.L480= | Silent (SNP) | VAF 20/185 reads (11%) | catalogued as COSV60215155; called by muse, mutect2, varscan2
- GC | c.375T>A p.A125= | Silent (SNP) | VAF 18/149 reads (12%) | catalogued as COSV99910057; called by muse, mutect2, varscan2
- GRIN2A | c.2943G>A p.Q981= | Silent (SNP) | VAF 13/111 reads (12%) | catalogued as COSV100410719; called by muse, mutect2, varscan2
- GRM1 | c.750G>A p.Q250= | Silent (SNP) | VAF 19/115 reads (17%) | catalogued as COSV99268353; called by muse, mutect2, varscan2
- HNMT | c.846T>C p.N282= | Silent (SNP) | VAF 27/120 reads (23%) | catalogued as COSV99699057; called by muse, mutect2, varscan2
- HS3ST4 | c.633C>G p.R211= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs1293944892, COSV100502515, COSV58800117; called by muse, mutect2, varscan2
- IGHV3-33 | c.186G>A p.K62= | Silent (SNP) | VAF 8/175 reads (5%) | catalogued as rs748213760; called by muse, mutect2
- ITGA4 | c.1573A>C p.R525= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV99276701; called by muse, mutect2, varscan2
- ITGB3 | c.468C>T p.S156= | Silent (SNP) | VAF 14/124 reads (11%) | catalogued as COSV101457656; called by muse, mutect2, varscan2
- JPT2 | c.543G>T p.P181= | Silent (SNP) | VAF 18/106 reads (17%) | catalogued as COSV50189505, COSV99936214; called by muse, mutect2, varscan2
- KCNK4 | c.1008C>A p.A336= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as COSV100107822; called by muse, mutect2, varscan2
- KHSRP | c.1197T>G p.G399= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs1206514254, COSV101231234; called by muse, mutect2, varscan2
- KIF21A | c.1593C>T p.D531= | Silent (SNP) | VAF 10/105 reads (10%) | catalogued as COSV100735590; called by muse, mutect2
- KIF4B | c.1473G>A p.A491= | Silent (SNP) | VAF 14/110 reads (13%) | catalogued as rs762593011; called by muse, mutect2, varscan2
- KIFAP3 | c.306A>T p.S102= | Silent (SNP) | VAF 35/136 reads (26%) | catalogued as rs1248140061, COSV100847102; called by muse, mutect2, varscan2
- KIR2DL4 | c.522G>T p.T174= (on ENST00000396284; = p.T135= on NM_001080770.2) | Silent (SNP) | VAF 12/250 reads (5%) | catalogued as rs767101253; called by muse, mutect2
- KIR3DL1 | c.1062C>A p.L354= | Silent (SNP) | VAF 16/152 reads (11%) | catalogued as rs766327086, COSV100373316; called by muse, mutect2
- KLHL32 | c.39G>T p.L13= | Silent (SNP) | VAF 3/40 reads (8%) | catalogued as COSV100987294, COSV65110281; called by muse, mutect2
- KYNU | c.960G>A p.L320= | Silent (SNP) | VAF 24/173 reads (14%) | catalogued as rs371795994; called by muse, mutect2, varscan2
- LILRB1 | c.1833G>C p.V611= (on ENST00000427581; = p.V560= on NM_006669.6) | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as COSV100207707; called by muse, mutect2
- LRRC14B | c.1209C>T p.R403= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs370865054; called by mutect2, varscan2
- LRRTM4 | c.1278T>A p.I426= | Silent (SNP) | VAF 6/71 reads (8%) | catalogued as rs1212764989, COSV101297691; called by muse, mutect2
- LY9 | c.849G>A p.L283= | Silent (SNP) | VAF 14/115 reads (12%) | catalogued as COSV99627305; called by muse, mutect2, varscan2
- MAPK14 | c.207C>T p.Y69= | Silent (SNP) | VAF 11/83 reads (13%) | catalogued as rs1469340250, COSV100005113; called by muse, mutect2, varscan2
- MAPK6 | c.153T>C p.I51= | Silent (SNP) | VAF 19/137 reads (14%) | catalogued as COSV99959356; called by muse, mutect2, varscan2
- MARCHF1 | c.399G>A p.E133= (on ENST00000274056; = p.E116= on NM_017923.4) | Silent (SNP) | VAF 15/91 reads (16%) | catalogued as COSV99922305; called by muse, mutect2, varscan2
- MCC | c.1341G>A p.L447= | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as COSV100203102; called by muse, mutect2
- MOV10 | c.804C>G p.T268= | Silent (SNP) | VAF 16/85 reads (19%) | catalogued as COSV100659734; called by muse, mutect2, varscan2
- MTHFD1 | c.1203C>T p.L401= | Silent (SNP) | VAF 6/120 reads (5%) | catalogued as COSV53704883; called by muse, mutect2
- MUC16 | c.18603C>T p.N6201= | Silent (SNP) | VAF 16/104 reads (15%) | catalogued as COSV101200991; called by muse, mutect2, varscan2
- MUC16 | c.17601T>C p.P5867= | Silent (SNP) | VAF 34/151 reads (23%) | catalogued as COSV101200992; called by muse, mutect2, varscan2
- MYCBP2 | c.2829A>G p.G943= (on ENST00000357337; = p.G981= on NM_015057.5) | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as COSV100631403; called by muse, mutect2, varscan2
- MYOM1 | c.3135C>G p.L1045= | Silent (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- N6AMT1 | c.213T>G p.A71= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV100375065, COSV58135805; called by muse, mutect2, varscan2
- NLRP5 | c.240C>T p.F80= | Silent (SNP) | VAF 10/118 reads (8%) | catalogued as COSV101173840; called by muse, mutect2
- NNT | c.3225G>C p.A1075= | Silent (SNP) | VAF 14/113 reads (12%) | catalogued as rs746624459, COSV99239404; called by muse, mutect2, varscan2
- NRXN1 | c.1290C>A p.V430= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV100456464; called by muse, mutect2, varscan2
- OR1J4 | c.735C>T p.L245= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as COSV100534315; called by muse, mutect2, varscan2
- OR2AG1 | c.204C>A p.L68= | Silent (SNP) | VAF 17/169 reads (10%) | catalogued as COSV100264946; called by muse, mutect2, varscan2
- OR2T12 | c.606G>A p.V202= | Silent (SNP) | VAF 9/120 reads (8%) | catalogued as COSV100527934; called by muse, mutect2
- OR2T4 | c.126G>T p.S42= | Silent (SNP) | VAF 8/180 reads (4%) | called by muse, mutect2
- OR2T8 | c.228G>T p.V76= | Silent (SNP) | VAF 24/200 reads (12%) | catalogued as COSV100178425; called by muse, mutect2, varscan2
- OR52E6 | c.405C>A p.T135= | Silent (SNP) | VAF 11/229 reads (5%) | called by muse, mutect2
- PATE2 | c.327C>T p.L109= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as COSV100653483; called by muse, mutect2, varscan2
- PCDH7 | c.2694A>G p.V898= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as rs538085533, COSV100688569; called by muse, mutect2, varscan2
- PCDHA7 | c.144C>T p.I48= | Silent (SNP) | VAF 16/136 reads (12%) | catalogued as COSV65342235, COSV65347101; called by muse, mutect2, varscan2
- PCDHA8 | c.798T>C p.A266= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV100970948; called by muse, mutect2, varscan2
- PCDHGB3 | c.1228C>T p.L410= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV99544482; called by muse, mutect2, varscan2
- PFAS | c.828C>A p.I276= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV100119094; called by muse, mutect2, varscan2
- PIK3CG | c.3114A>C p.G1038= | Silent (SNP) | VAF 20/134 reads (15%) | catalogued as rs1204980429, COSV100783088; called by muse, mutect2, varscan2
- PKHD1 | c.312G>T p.L104= | Silent (SNP) | VAF 29/155 reads (19%) | catalogued as COSV100584218; called by muse, mutect2, varscan2
- PLCH1 | c.543A>G p.R181= (on ENST00000340059 / NM_001130960.2; = p.R193= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/125 reads (12%) | catalogued as COSV100397974; called by muse, mutect2, varscan2
- PLEKHS1 | c.957G>A p.E319= (on ENST00000369310 / NM_182601.1; = p.E339= on NM_024889.5) | Silent (SNP) | VAF 7/84 reads (8%) | catalogued as COSV100613269, COSV63054145; called by muse, mutect2
- PPP1R26 | c.2769C>A p.G923= | Silent (SNP) | VAF 32/100 reads (32%) | catalogued as rs767573787, COSV100778139; called by muse, mutect2, varscan2
- PRLR | c.1329T>A p.P443= | Silent (SNP) | VAF 30/169 reads (18%) | catalogued as COSV99184699; called by muse, mutect2, varscan2
- PRR23B | c.735C>T p.H245= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as rs1322951360, COSV61493461, COSV61494304; called by muse, mutect2, varscan2
- PRUNE2 | c.1425G>T p.G475= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV100945008; called by muse, mutect2, varscan2
- PSMA2 | c.567T>C p.H189= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as rs1376309232, COSV99785964; called by muse, mutect2, varscan2
- RBP3 | c.2613C>A p.P871= | Silent (SNP) | VAF 15/45 reads (33%) | called by muse, mutect2, varscan2
- REC8 | c.348C>T p.S116= | Silent (SNP) | VAF 75/178 reads (42%) | catalogued as COSV100269191; called by muse, mutect2, varscan2
- REEP3 | c.141C>T p.L47= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV100005216; called by muse, mutect2, varscan2
- RNF19B | c.1467G>T p.L489= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as COSV99331669; called by muse, mutect2, varscan2
- RPL7 | c.303G>A p.V101= | Silent (SNP) | VAF 15/147 reads (10%) | catalogued as COSV99536447; called by muse, mutect2, varscan2
- RRN3 | c.822T>C p.C274= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as COSV99549022; called by muse, mutect2, varscan2
- RTN4RL1 | c.339G>A p.L113= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV100486742; called by muse, mutect2, varscan2
- SCUBE1 | c.471C>A p.I157= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs1425892893; called by muse, mutect2
- SEC16B | c.2106G>A p.A702= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as rs34633883; called by mutect2, varscan2
- SLC38A4 | c.126T>C p.F42= | Silent (SNP) | VAF 10/97 reads (10%) | catalogued as COSV99873064; called by muse, mutect2
- SLIT2 | c.3594G>C p.L1198= | Silent (SNP) | VAF 6/125 reads (5%) | catalogued as COSV99886438; called by muse, mutect2
- SLITRK2 | c.6G>A p.L2= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV100158105; called by muse, mutect2, varscan2
- SLITRK5 | c.102C>A p.V34= | Silent (SNP) | VAF 18/110 reads (16%) | catalogued as COSV100281081, COSV61525892; called by muse, mutect2, varscan2
- SLITRK5 | c.1275C>T p.R425= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV100281083; called by muse, mutect2, varscan2
- ST7 | c.21C>G p.G7= | Silent (SNP) | VAF 7/75 reads (9%) | catalogued as COSV99622723; called by muse, mutect2
- STOX2 | c.1167G>T p.L389= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV100409086; called by muse, mutect2, varscan2
- TBX21 | c.855C>T p.N285= | Silent (SNP) | VAF 10/121 reads (8%) | catalogued as rs1262526096, COSV51597865; called by muse, mutect2
- TDP1 | c.1417C>T p.L473= | Silent (SNP) | VAF 14/102 reads (14%) | catalogued as COSV100188037; called by muse, mutect2, varscan2
- TNR | c.453G>T p.L151= | Silent (SNP) | VAF 23/93 reads (25%) | catalogued as rs1406621546, COSV54901057; called by muse, mutect2, varscan2
- TRIM3 | c.1323C>T p.P441= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as rs756964309, COSV100624516; called by muse, mutect2, varscan2
- TRIM32 | c.303G>T p.R101= | Silent (SNP) | VAF 18/128 reads (14%) | catalogued as COSV100529659; called by muse, mutect2, varscan2
- TRIM67 | c.1668G>T p.G556= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as COSV100792193; called by muse, mutect2
- TRIM69 | c.1488C>T p.I496= (on ENST00000329464 / NM_182985.5; = p.I337= on NM_080745.5) | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV100274393; called by muse, mutect2, varscan2
- TRPC5 | c.1485C>A p.S495= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as COSV99462320; called by muse, mutect2, varscan2
- TRPM2 | c.555G>T p.R185= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV100309193, COSV55970616; called by muse, mutect2, varscan2
- TTN | c.52269A>G p.R17423= (on ENST00000591111; = p.R9999= on NM_003319.4) | Silent (SNP) | VAF 21/119 reads (18%) | catalogued as COSV100625400; called by muse, mutect2, varscan2
- TTN | c.1971T>A p.S657= (on ENST00000591111; = p.S611= on NM_003319.4) | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as COSV100625409; called by muse, mutect2
- TTN | c.1005G>T p.V335= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV100625412; called by muse, mutect2
- UXT | c.48A>G p.K16= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs376885210, COSV100243871; called by muse, mutect2, varscan2
- WNK1 | c.5640A>G p.A1880= (on ENST00000315939 / NM_018979.4; = p.A1632= on NM_014823.3) | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV100268226; called by muse, mutect2
- ZFAT | c.1371G>T p.V457= | Silent (SNP) | VAF 5/69 reads (7%) | called by muse, mutect2
- ZGRF1 | c.4626G>A p.L1542= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as COSV100349337; called by muse, mutect2
- ZNF425 | c.1011G>T p.R337= | Silent (SNP) | VAF 28/89 reads (31%) | catalogued as COSV100955577; called by muse, mutect2, varscan2
- ZNF518A | c.1311C>T p.S437= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as COSV100283657; called by muse, mutect2, varscan2
- ZNF804A | c.1749A>G p.K583= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as rs758427445, COSV100169595; called by muse, mutect2, varscan2
- AC024940.1 | n.4078A>C | RNA (SNP) | VAF 9/52 reads (17%) | called by muse, mutect2, varscan2
- AGAP7P | n.1336C>T | RNA (SNP) | VAF 8/164 reads (5%) | called by muse, mutect2
- AIRE | c.880-113G>T | Intron (SNP) | VAF 15/127 reads (12%) | catalogued as COSV99381350; called by muse, mutect2, varscan2
- ANK1 | c.5619+313G>T | Intron (SNP) | VAF 7/119 reads (6%) | called by muse, mutect2
- CD99 | c.475+962G>T | Intron (SNP) | VAF 7/30 reads (23%) | catalogued as COSV101152291; called by muse, mutect2, varscan2
- CEP295 | chr11:93735192 T>C | 3'Flank (SNP) | VAF 11/44 reads (25%) | called by muse, mutect2, varscan2
- CHD4 | c.1064-18T>A | Intron (SNP) | VAF 12/105 reads (11%) | catalogued as COSV100538884; called by muse, mutect2, varscan2
- CR1 | c.487+12315C>A | Intron (SNP) | VAF 24/101 reads (24%) | catalogued as COSV100887970; called by muse, mutect2, varscan2
- DCHS2 | n.8355G>A | RNA (SNP) | VAF 10/112 reads (9%) | catalogued as rs375321525, COSV100602796; called by muse, mutect2
- FABP5P3 | chr7:152445705 C>A | 3'Flank (SNP) | VAF 16/128 reads (13%) | called by muse, mutect2, varscan2
- HERC2P3 | n.2250T>A | RNA (SNP) | VAF 7/95 reads (7%) | called by muse, mutect2
- LINC02694 | n.219G>T | RNA (SNP) | VAF 7/63 reads (11%) | catalogued as COSV100601936; called by muse, mutect2
- LPAL2 | n.374A>T | RNA (SNP) | VAF 16/130 reads (12%) | called by muse, mutect2, varscan2
- MIR517B | n.45C>G | RNA (SNP) | VAF 35/151 reads (23%) | called by muse, mutect2, varscan2
- MIR517C | n.24T>C | RNA (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- NBPF11 | c.-548-2951G>T | Intron (SNP) | VAF 18/133 reads (14%) | called by muse, mutect2, varscan2
- RPP38 | chr10:15096706 T>G | 5'Flank (SNP) | VAF 15/88 reads (17%) | called by muse, mutect2, varscan2
- SLC26A7 | c.1935+227C>T | Intron (SNP) | VAF 7/45 reads (16%) | catalogued as COSV99404085; called by muse, mutect2, varscan2
- SSPOP | n.2955T>C | RNA (SNP) | VAF 21/125 reads (17%) | catalogued as rs1329614302, COSV100022873; called by muse, mutect2, varscan2
- TCEAL6 | c.*2G>T | 3'UTR (SNP) | VAF 16/51 reads (31%) | catalogued as COSV101036009; called by muse, mutect2, varscan2
- TFE3 | c.*236G>T | 3'UTR (SNP) | VAF 14/46 reads (30%) | catalogued as COSV100252770; called by muse, mutect2, varscan2
- XIST | n.7808C>G | RNA (SNP) | VAF 9/62 reads (15%) | called by muse, mutect2, varscan2
